Somatic mutation profile of tumor specimen TARGET-30-PARMDD-01A (aliquot TARGET-30-PARMDD-01A-01D) from TARGET case TARGET-30-PARMDD, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.2 years (1,180 days).
Specimen TARGET-30-PARMDD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38317297-0811-4d93-a8f9-6e5cb0c8a647.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARMDD-10A (Blood Derived Normal), aliquot TARGET-30-PARMDD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3082e7f-915b-4f55-9e8b-7ebbb48cc40b

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLDN3 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs782121496; called by mutect2, varscan2
- MGA | c.2750C>G p.S917C | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV54953026; called by muse, mutect2
- MYH4 | c.710A>G p.K237R | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1397605994; called by muse, mutect2
- KCNMA1 | c.2664G>A p.R888= (on ENST00000286628 / NM_001161352.2; = p.R830= on NM_002247.4) | Silent (SNP) | VAF 13/176 reads (7%) | catalogued as rs1430010589; called by muse, mutect2
- TAS2R60 | c.108C>A p.G36= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as COSV60331023; called by muse, mutect2, varscan2
